Gene-level copy-number profile of tumor specimen TCGA-61-2097-01A from TCGA case TCGA-61-2097, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 71.1 years (25,961 days).
Specimen TCGA-61-2097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1cddea11-beb7-443f-9faa-f13824cc3e35.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2097-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/23e8e440-6558-4089-8eca-f15df90c60e1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,068; copy number 2: 20,934; copy number 3: 6,434; copy number 4: 27,014; copy number 5: 2,340; copy number 6: 1,502; copy number 8: 351; copy number 10: 170.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2097-01A-02D-0663-01): tumor purity 0.61, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 170 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:141,968,091–145,066,685, 170 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,068. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
